Surgical pathology report (de-identified scan), TCGA case TCGA-66-2794, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2794-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lung, among others

Clinical diagnosis and question

Bronchial carcinoma left lung (squamous cell carcinoma Tc3 N2 stage IIIA). Asbestos exposure.

REPORT ON FINDINGS**Macroscopy**

1.) Left lung: inflated, fixed left lung measuring 16 x 11 cm and up to 27 cm high, central bronchus resection plane located 3.5 cm proximal to the bifurcation of the upper lobe bronchus. Main bronchus largely skeletonized. At the hilus a 2 cm adherent membranous part (pericardial sac?). At the main bronchus a 1.8 cm lesioned grayish-black node close to the bronchus resection plane. In the apicolateral region over S1 a 1 cm area of pleural adhesion, upper lobe and intermediate bronchus ostium constricted by a central, moderately firm, pale brown whitish tumor, max. 4.8 cm in size, with patchy grayish-black pigmentation in parts and a predominantly clear and somewhat arcuate demarcation, with the main mass more in the upper lobe and also questionably involving some blackish nodes up to 1 cm. Tumor mucosa of the named bronchial sections roughened and cracked over the tumor. Tumor extension right up to the hilar resection surface and questionably up to the suspected part of the pericardial sac. Tumor spread to about 0.3 cm proximal to the bifurcation of the upper lobe bronchus into the wall of the main bronchus, distance from the central bronchus resection plane at least 2 cm. At most a slight narrowing of central blood vessels by the tumor. Peripheral bronchi of the upper lobe, especially of segments 4 and 5, dilated and partly filled with thick mucus. Apical parenchyma in S1 shows slight circumscribed rarefaction, rest of parenchyma inconspicuous. Subpleural lateral region in S5 has a 0.4 cm flat blackish node.

2.) Hilar LN (station 10) left: 1.5 cm gr. lesioned node or node part.

3.) Pulmonary ligament LN (station 9) left: 1.5 cm node with sparse surrounding tissue

4.) Paraesophageal LN (station 8) left: two lesioned nodes, 0.7 and 0.3 cm.

5.) Paraaortic LN (station 6) left: 0.5 cm lesioned nodes.

6.) Subaortic LN (aortopulmonary window) (station 5) left: two partly lesioned nodes, 0.8 and 0.7 cm

7.) Low paratracheal LN (station 4) left: 2.5 cm node partly occupied by tissue suspected to be of tumorous.

8.) Prevascular and retrotracheal LN (station 3) left: two lesioned nodes or node parts, 1.2 and 0.9 cm.

9.) Hilar LN (station 10) right: three lesioned nodes or node parts between 0.4 and 1.3 cm.

Examined:

1) a: Tumor with rest of parenchyma and upper lobe bronchus and involved node, b: tumor with bronchus at level of upper lobe bronchus bifurcation and also with hilar resection surface (color-marked) and questionable part of pericardial sac, c: questionable part of pericardial sac (resection margin color-marked) and subpleural node in S5, d: tumor with hilar resection surface (color-marked), e: S5 intermediate to peripheral, f: S1 apical and main bronchus almost proximal upper lobe bronchus bifurcation, g: central bronchus and resection margins of pulmonary veins, h: pulmonary artery and node at main bronchus, i: segment 10 dorsal,

2.) - 6.) 4 8.) and 9.) All material,

7.) 1 section,

17 blocks, partly Elastica-van Gieson, PAS, diastase-PAS, iron staining.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Central and locally advanced bronchopulmonary, histologically poorly differentiated, large-cell, focally keratinizing squamous cell carcinoma of left lung with main localization in the upper lobe.

TNM classification according to this picture pT4 pN2 pMX V1 R0, stage IIIB.

C14 I M8070/3.

Secondary diagnosis/diagnoses:

Bronchiectases peripheral to the tumors mainly in the lingula and focal retention signs of lung parenchyma in S5. In the subpleural region and the mantle zone of S1 manifest moderate pulmonary emphysema. Pleural adhesion zone at the apex of the upper lobe (sample 1.). Lymph nodes with reactive lesions and anthracotic pigment deposits (samples 2. - 6., 8. and 9.).

Remark/addendum:

The carcinoma has spread to the distal part of the main bronchus and associated fatty tissue directly localized to the bifurcation of the upper lobe bronchus, which results in the category pT4. The tumor has also spread to within 20 micrometers of the hilar resection surface. Metastases are seen in the peribronchial and hilar lymph nodes in the main preparation and the lymph node of sample 7. The resection margin of bronchi and vessels, the visceral pleura, the co-resected piece of pericardial sac and the lymph nodes of samples 2. - 6, 8. and 9. are tumor-free.

No asbestos bodies are found in the prepared section planes. But very much further-reaching investigations, especially dust analyses, are needed to determine the asbestos exposure of the lung.

Source: NCI Genomic Data Commons file 626d261d-a964-47e7-985b-c39c69f3d9a0 (TCGA-66-2794.B0788A69-3DD0-42D6-8564-958A0108654B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).